Gene-level copy-number profile of tumor specimen ALCH-AE2N-TTP1-A from ALCHEMIST case ALCH-AE2N, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 71.9 years (26,266 days).
Specimen ALCH-AE2N-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 4bbb42a8-2efc-476b-80b2-8b465705ed50.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-AE2N-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,226 have no estimate.
https://portal.gdc.cancer.gov/files/5f51fae2-8153-4c21-98b7-443d266e1d49

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 5; copy number 1: 2,824; copy number 2: 51,423; copy number 3: 4,142; copy number 4: 3.

Homozygous deletions (total copy number 0; autosomes only): 5 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:1,267,353–1,269,267, 1 gene: AC073094.1.
- chr16:1,770,286–1,781,708, 3 genes (within-gene range 0–2): NME3, MRPS34, EME2.
- chr22:41,938,737–41,947,152, 1 gene: CENPM.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 2,824. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
